FM case AD4914 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Paragangliomas and Glomus Tumors.
https://portal.gdc.cancer.gov/cases/442e6675-cb6d-4ae0-89e9-ba568ba973cb

Male, 47.7 years: Paraganglioma, NOS (ICD-O-3 8680/1); metastasis biopsied or resected from the lung. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Metastatic.
